Surgical pathology report (de-identified scan), TCGA case TCGA-G3-AAUZ, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-AAUZ-01A (Primary Tumor).

[page 1 of 2]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected

Time Reported

Order Number

Status

Final

Time Received

Time Transmitted

Ordering Provider

Relevant Information

Location

Report Patient

Name:

Demographics (for

verification purposes)

Date of Birth:

Sex: M

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number

Collected Date/Time

Received Date/Time

Pathologist

Specimen Description

A. Gallbladder @

B. Segment 4/5 liver @

C. Final margin @

Clinical Information

Hx. htc and hep B.

Diagnosis

A. Gallbladder, Cholecystectomy:

- Negative for malignancy.

B. Liver, Segment 4/5, Resection:

- Well differentiated hepatocellular carcinoma, 4.4 x 2.7 x 2.3 cm.

- 0.1 cm to the blue inked specimen margin.

- Background liver show portal inflammation and steatosis (20%).

C. Final Margin, Biopsy:

- Liver parenchyma, negative for hepatocellular carcinoma.

Reported by:

Electronically signed by:

Verified:

Gross Description

Received are specimen containers A to C. All requisitions and specimen containers are labelled with the patient's name, . The cassettes and identifiers are labelled with the Surgical Number

A. Specimen is received in formalin. The container is designated "gallbladder @ ". The specimen consists of a non-intact gallbladder measuring 6.8 x 2.3 x 1.2 cm. The serosal surface appears smooth and unremarkable. The lumen contains green bile and no calculi, and the cystic duct appears patent. The mucosa is granular, and the wall averages 0.2 cm in thickness. The cystic duct lymph node is identified and measures 0.6 cm in greatest dimension. Representative sections of the gallbladder are submitted in A1. The entire lymph node is bisected and submitted in A2.

B. Specimen is received fresh and is submitted in formalin. The container is designated "segment 4/5 liver @ ". The specimen consists of an 81.3 g partial hepatectomy specimen measuring 6.4 x 6.2 x 5.6 cm. The capsular surface appears smooth and unremarkable. Roughened surgical resection margin is dyed with blue ink. The specimen is serially sectioned to reveal a well circumscribed, ovoid mass which has lobular features on cut surface. This mass measures 4.4 x 2.7 x 2.3 cm and grossly comes right to the capsular surface, but does not grossly appear to invade the surface and to within 0.1 cm of the blue inked surgical resection margin. No other lesions are grossly identified.

ICD-0.3

Carcinoma, hepatocellular NOS 8170/3

Site: Liver C22.0

JN 5/20/14

[page 2 of 2]
B1-B3 representative sections of the tumor and grossly closest point of invasion to both capsular surface and blue inked surgical resection margin.
B4 further representative section of the tumor.
B5 representative section of normal liver adjacent to the liver.
C. Specimen is received fresh and submitted in formalin. The container is designated "final margin" and consists of a single, soft, dark tan, triangular portion of tissue measuring 1.5 x 1.0 x 0.7 cm. Surgical resection margin is grossly identified which is dyed with blue ink. The specimen is serially sectioned and submitted in toto in one block.

Pathologist Comment
Case seen in review by

Accession Number
Encounter Number
Patient Location

Source: NCI Genomic Data Commons file 2e4842c0-677c-466e-a47a-dd3d507b63d2 (TCGA-G3-AAUZ.09055681-FB0F-4960-86A0-5D6EBD08FAED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).